Somatic mutation profile of tumor specimen TCGA-B5-A0JZ-01A (aliquot TCGA-B5-A0JZ-01A-11W-A062-09) from TCGA case TCGA-B5-A0JZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 60.5 years (22,106 days).
Specimen TCGA-B5-A0JZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98bf3e79-c2a2-44c5-ba52-f47b9ca0ea05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0JZ-10A (Blood Derived Normal), aliquot TCGA-B5-A0JZ-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4af582cb-aa0a-4593-8694-155264d16a7e

The open-access MAF lists 660 somatic variants for this specimen: 523 protein-altering or splice-affecting, 119 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 299, Frame Shift Del 147, Silent 119, Nonsense Mutation 26, Frame Shift Ins 25, In Frame Del 12, Splice Site 9, Intron 5, RNA 4, Splice Region 4, 5'Flank 3, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.126dup p.L43Afs*125 | Frame Shift Ins (INS) | VAF 8/17 reads (47%) | catalogued as rs180177171; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ATM | c.640del p.S214Pfs*16 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs786204543; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- FANCG | c.1158del p.S387Pfs*16 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs757418016; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FKBP10 | c.743del p.P248Hfs*11 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs1555616552, COSV58637000; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MFRP | chr11:119345563 del G | 5'Flank (DEL) | VAF 8/20 reads (40%) | catalogued as rs587776596, CD052468, COSV64129114; ClinVar: pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 79/222 reads (36%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- STXBP1 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1064794322, COSV64813096; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.5003G>A p.R1668H | Missense Mutation (SNP) | VAF 76/239 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs566240276, COSV70028171; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCD1 | c.1394-1G>T p.X465_splice | Splice Site (SNP) | VAF 4/12 reads (33%) | catalogued as COSV54386578; called by muse, mutect2
- ABL1 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.503); catalogued as rs756003964, COSV59333693; called by muse, mutect2, varscan2
- ABO | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1212134673, COSV71743608; called by muse, mutect2, varscan2
- AC098582.1 | c.2075C>A p.P692H | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV52022559; called by muse, mutect2, varscan2
- ACSS3 | c.1051A>G p.I351V | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV54096240; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 92/244 reads (38%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADARB2 | c.2005C>T p.H669Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs917882093, COSV67182530; called by muse, mutect2, varscan2
- ADGRG5 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 33/93 reads (35%) | catalogued as COSV61083949; called by muse, mutect2, varscan2
- ADGRG5 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs142292696; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 67/198 reads (34%) | catalogued as rs761350619; called by mutect2, varscan2
- AK7 | c.1292A>C p.E431A | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as COSV50876228; called by muse, mutect2, varscan2
- AKAP13 | c.7150C>T p.R2384W (on ENST00000394518 / NM_007200.5; = p.R2388W on NM_006738.6) | Missense Mutation (SNP) | VAF 297/811 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779871275, COSV100774779, COSV63464583; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 74/210 reads (35%) | catalogued as COSV62339755; called by mutect2, varscan2
- AL592490.1 | c.1673A>G p.Y558C | Missense Mutation (SNP) | VAF 88/355 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV69427028; called by muse, mutect2, varscan2
- ALKBH6 | c.304G>A p.V102M (on ENST00000252984 / NM_001297701.2; = p.V130M on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs750624920, COSV53325280; called by muse, mutect2, varscan2
- ALX4 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs747909089, COSV61327684; called by muse, mutect2, varscan2
- ANGEL1 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.148); catalogued as rs747699999, COSV51874440; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs749182271; called by mutect2, varscan2
- ANKRD26 | c.2558A>G p.Q853R | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV65776772; called by muse, mutect2, varscan2
- ANP32B | c.416T>C p.L139P | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59587299; called by muse, mutect2, varscan2
- AP1M1 | c.382A>G p.S128G | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV52227689; called by muse, mutect2, varscan2
- AP1M2 | c.1150T>C p.Y384H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51568382; called by muse, mutect2, varscan2
- APOBEC2 | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.175); catalogued as COSV55143130; called by muse, mutect2
- ARHGEF12 | c.1906G>A p.V636M | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs200737612, COSV63103584; called by muse, mutect2, varscan2
- ARL13B | c.1133del p.P378Lfs*49 (on ENST00000394222 / NM_001174150.2; = p.P271Lfs*49 on NM_144996.4) | Frame Shift Del (DEL) | VAF 27/114 reads (24%) | catalogued as COSV57399035; called by mutect2, pindel, varscan2
- ASCC3 | c.489dup p.G164Wfs*2 | Frame Shift Ins (INS) | VAF 46/136 reads (34%) | catalogued as rs747570359; called by mutect2, varscan2
- ASXL2 | c.1351G>T p.G451C | Missense Mutation (SNP) | VAF 160/529 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV55463132; called by muse, mutect2
- ATG16L2 | c.1355G>A p.G452D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV58362383; called by muse, mutect2, varscan2
- ATG2A | c.1298del p.G433Vfs*2 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | catalogued as rs751537436, COSV65967044; called by mutect2, pindel, varscan2
- ATP11C | c.674T>C p.V225A | Missense Mutation (SNP) | VAF 92/276 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.794); catalogued as COSV59568989; called by muse, varscan2
- ATP8A1 | c.3320C>T p.A1107V | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV52541405; called by muse, mutect2, varscan2
- AURKB | c.475dup p.R159Pfs*15 | Frame Shift Ins (INS) | VAF 6/53 reads (11%) | catalogued as rs745673717; called by pindel, varscan2
- AUTS2 | c.2399C>T p.P800L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61417950; called by muse, mutect2, varscan2
- AXIN1 | c.792del p.G265Efs*149 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as COSV51989295; called by mutect2, pindel, varscan2
- BACH1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 107/285 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.073); catalogued as COSV54519973; called by muse, mutect2, varscan2
- BAG3 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV64842338; called by muse, mutect2, varscan2
- BAIAP2 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as COSV58337817; called by muse, mutect2, varscan2
- BCAN | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61258145; called by muse, mutect2, varscan2
- BCOR | c.19del p.L7Cfs*9 | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | catalogued as COSV60718182; called by mutect2, pindel, varscan2
- BICDL1 | c.1666dup p.D556Gfs*2 | Frame Shift Ins (INS) | VAF 8/70 reads (11%) | catalogued as rs755289629; called by mutect2, pindel
- BOC | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV56352012; called by muse, mutect2, varscan2
- BPTF | c.2805G>T p.K935N | Missense Mutation (SNP) | VAF 100/251 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV58841875; called by muse, mutect2, varscan2
- BRF1 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1315588255, COSV59271311; called by muse, mutect2, varscan2
- BRWD1 | c.5912C>T p.T1971I | Missense Mutation (SNP) | VAF 75/196 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV60899752; called by muse, mutect2, varscan2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | catalogued as COSV62298237; called by mutect2, pindel, varscan2
- C16orf70 | c.1230del p.R411Gfs*6 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | catalogued as rs539297455, COSV54625370; called by mutect2, varscan2
- C1R | c.73C>A p.L25M (on ENST00000536053 / NM_001354346.2; = p.L11M on NM_001733.7) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV56925976; called by muse, mutect2, varscan2
- C3 | c.4134G>T p.Q1378H | Missense Mutation (SNP) | VAF 97/290 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV55576930; called by muse, mutect2, varscan2
- CA1 | c.686G>T p.S229I | Missense Mutation (SNP) | VAF 108/333 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV56279308; called by muse, mutect2, varscan2
- CA6 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.336); catalogued as COSV66262535; called by muse, mutect2, varscan2
- CACNA1E | c.5894C>A p.S1965Y | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.397); catalogued as COSV62406616; called by muse, mutect2, varscan2
- CACNG4 | c.855G>T p.K285N | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV50926240; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 74/249 reads (30%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CANX | c.1305del p.F435Lfs*12 | Frame Shift Del (DEL) | VAF 114/175 reads (65%) | catalogued as rs760711956; called by mutect2, varscan2
- CAPG | c.494G>T p.C165F | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55708130; called by muse, mutect2, varscan2
- CAPN6 | c.1102A>G p.M368V | Missense Mutation (SNP) | VAF 443/1492 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV60696109; called by muse, mutect2, varscan2
- CARS1 | c.1147-1G>T p.X383_splice | Splice Site (SNP) | VAF 14/45 reads (31%) | catalogued as COSV53457300; called by muse, mutect2, varscan2
- CARS2 | c.544C>G p.R182G | Missense Mutation (SNP) | VAF 237/688 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV57286364, COSV57287518; called by muse, mutect2, varscan2
- CATIP | c.319+1G>A p.X107_splice | Splice Site (SNP) | VAF 20/57 reads (35%) | catalogued as rs775257872, COSV56823562, COSV99179572; called by muse, mutect2, varscan2
- CCDC127 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57257588; called by muse, mutect2, varscan2
- CCDC136 | c.2983A>G p.K995E | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV52802304; called by muse, mutect2, varscan2
- CCDC158 | c.610dup p.I204Nfs*3 | Frame Shift Ins (INS) | VAF 88/271 reads (32%) | catalogued as rs1248476350; called by mutect2, varscan2
- CCDC185 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV64821163; called by muse, mutect2, varscan2
- CCDC57 | c.2486C>T p.T829I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV66438428; called by muse, mutect2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 36/92 reads (39%) | catalogued as rs762553129; called by mutect2, varscan2
- CCT2 | c.670del p.I224Lfs*3 | Frame Shift Del (DEL) | VAF 49/134 reads (37%) | catalogued as rs1200580878; called by mutect2, pindel, varscan2
- CECR2 | c.3016C>T p.Q1006* (on ENST00000342247 / NM_001290047.2; = p.Q822* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV52844880; called by muse, mutect2, varscan2
- CEP104 | c.1699A>T p.I567F | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV65518401; called by muse, mutect2, varscan2
- CEP57L1 | c.1162G>A p.V388I | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61245376; called by muse, mutect2, varscan2
- CEP68 | c.1687G>A p.V563I | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370783857, COSV53125834, COSV53126176; called by muse, mutect2, varscan2
- CGNL1 | c.1994A>G p.N665S | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV55571609; called by muse, mutect2, varscan2
- CHCHD5 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs952520714, COSV61424451; called by muse, mutect2, varscan2
- CLPB | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747344641, COSV53631430; called by muse, mutect2, varscan2
- CMTM7 | c.432G>T p.A144= | Splice Region (SNP) | VAF 41/120 reads (34%) | catalogued as COSV58551451; called by muse, mutect2, varscan2
- CNGA4 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); catalogued as rs1353756952, COSV66006345; called by muse, mutect2, varscan2
- CNGB1 | c.2902C>T p.R968W | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs780651730, COSV51901611; called by muse, mutect2, varscan2
- COL11A1 | c.3929C>A p.P1310H | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV62189985; called by muse, mutect2, varscan2
- COLEC12 | c.1580G>C p.G527A | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV68372251; called by muse, mutect2, varscan2
- COLGALT2 | c.767del p.P256Hfs*41 | Frame Shift Del (DEL) | VAF 40/140 reads (29%) | catalogued as COSV100730886; called by mutect2, pindel, varscan2
- CPZ | c.1424G>A p.C475Y (on ENST00000360986 / NM_001014447.3; = p.C464Y on NM_003652.3) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59924311; called by muse, mutect2
- CRKL | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 124/379 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV62882811, COSV62883784; called by muse, mutect2, varscan2
- CRTAC1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764021235, COSV53997045; called by muse, mutect2, varscan2
- CUL9 | c.2113C>A p.L705I | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.525); catalogued as COSV52731526; called by muse, mutect2, varscan2
- CXorf65 | c.320-1G>A p.X107_splice | Splice Site (SNP) | VAF 18/54 reads (33%) | catalogued as COSV52149476; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as rs756254049; called by mutect2, pindel, varscan2
- CYP4F8 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs760985202, COSV57854707; called by muse, mutect2, varscan2
- DAOA | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); catalogued as rs368169582; called by muse, mutect2
- DCAF10 | c.758C>A p.T253N | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.912); catalogued as COSV54289575; called by muse, mutect2, varscan2
- DCAF12L1 | c.1172T>C p.L391P | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV64422311; called by muse, mutect2, varscan2
- DCAF4L1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); catalogued as COSV60786317; called by muse, mutect2, varscan2
- DCTN1 | c.1927C>T p.R643* | Nonsense Mutation (SNP) | VAF 32/76 reads (42%) | catalogued as rs866457869, COSV62619563; called by muse, mutect2, varscan2
- DDX17 | c.2051G>A p.R684Q | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as rs1246635514, COSV53247807, COSV53248867; called by muse, mutect2, varscan2
- DHRS7C | c.576C>T p.Y192= (on ENST00000330255 / NM_001220493.2; = p.Y191= on NM_001105571.3) | Splice Region (SNP) | VAF 12/34 reads (35%) | catalogued as COSV57651769; called by muse, mutect2, varscan2
- DISP1 | c.810G>A p.W270* | Nonsense Mutation (SNP) | VAF 30/85 reads (35%) | catalogued as COSV52662173; called by muse, mutect2, varscan2
- DISP3 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV53826701; called by muse, mutect2, varscan2
- DNAH10 | c.1685G>A p.R562H (on ENST00000409039; = p.R501H on NM_207437.3) | Missense Mutation (SNP) | VAF 94/264 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as rs201031616, COSV68991821; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 67/152 reads (44%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAH8 | c.1496A>G p.H499R | Missense Mutation (SNP) | VAF 26/588 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV59464872; called by muse, mutect2
- DNAJC11 | c.467A>G p.Q156R | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV53788701; called by muse, mutect2, varscan2
- DNER | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 100/278 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs368405241, COSV59171289; called by muse, mutect2, varscan2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs748134881; called by mutect2, varscan2
- DOCK9 | c.6167C>T p.A2056V (on ENST00000376460 / NM_001366676.2; = p.A2057V on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764927576, COSV59636582, COSV59638846; called by muse, mutect2, varscan2
- DOCK9 | c.83C>G p.A28G | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as COSV59636600; called by muse, varscan2
- DPYSL2 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100233688, COSV60784114; called by muse, mutect2, varscan2
- EDAR | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM087221, COSV51505234; called by muse, mutect2, varscan2
- EFHC1 | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs369777400, COSV104427278; ClinVar: uncertain significance; called by muse, mutect2
- EGF | c.1282G>A p.V428M | Missense Mutation (SNP) | VAF 23/377 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1351225360, COSV54481564; called by muse, mutect2
- EGFR | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51823220; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.371); catalogued as COSV57517053; called by muse, mutect2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 100/295 reads (34%) | catalogued as rs766700925; called by mutect2, varscan2
- ERICH3 | c.4467G>T p.E1489D | Missense Mutation (SNP) | VAF 304/878 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.766); catalogued as COSV58612662; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 39/128 reads (30%) | catalogued as rs775950025; called by mutect2, varscan2
- EXOC5 | c.2113C>T p.R705* | Nonsense Mutation (SNP) | VAF 96/313 reads (31%) | catalogued as rs1450931479, COSV61771611; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 23/62 reads (37%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAM122B | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 62/173 reads (36%) | catalogued as COSV53231923; called by muse, mutect2, varscan2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 58/170 reads (34%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM47C | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 32/446 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.281); catalogued as rs782761094, COSV63728758; called by muse, mutect2
- FANCG | c.622C>A p.L208M | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); catalogued as COSV62721398; called by muse, mutect2, varscan2
- FAR2 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs370381799; called by muse, mutect2, varscan2
- FAT1 | c.11875C>T p.Q3959* | Nonsense Mutation (SNP) | VAF 42/128 reads (33%) | catalogued as rs762097716, COSV71675141; called by muse, mutect2, varscan2
- FERMT2 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 125/335 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as COSV58408286; called by muse, mutect2, varscan2
- FHOD3 | c.3812G>C p.R1271T (on ENST00000359247 / NM_001281739.3; = p.R1288T on NM_025135.5) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV57180702; called by muse, mutect2, varscan2
- FKBP15 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV53037180; called by muse, mutect2, varscan2
- FKBP8 | c.1076del p.T359Rfs*93 (on ENST00000222308 / NM_001308373.2; = p.T360Rfs*93 on NM_012181.5) | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | catalogued as COSV55893271; called by mutect2, varscan2
- FLII | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 4/8 reads (50%) | catalogued as COSV58946425; called by muse, varscan2
- FLNB | c.680A>G p.E227G | Missense Mutation (SNP) | VAF 69/201 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55886877; called by muse, mutect2, varscan2
- FOXA3 | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 90/313 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56216839; called by muse, mutect2, varscan2
- GBP6 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 26/126 reads (21%) | catalogued as rs1223503314, COSV65012060; called by muse, mutect2, varscan2
- GEN1 | c.130del p.M44* | Frame Shift Del (DEL) | VAF 34/186 reads (18%) | catalogued as rs748084139; called by mutect2, pindel, varscan2
- GFRA1 | c.792dup p.T265Yfs*20 | Frame Shift Ins (INS) | VAF 16/50 reads (32%) | catalogued as rs753876091; called by mutect2, varscan2
- GIGYF2 | c.2887G>C p.E963Q | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV65251621; called by muse, mutect2, varscan2
- GLRB | c.608G>T p.S203I | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV52419770; called by muse, mutect2, varscan2
- GON4L | c.6205G>A p.G2069R | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.019); catalogued as rs1199565772, COSV55198270; called by muse, mutect2
- GPATCH8 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59196200; called by muse, mutect2, varscan2
- GPBP1 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149343603; called by muse, mutect2, varscan2
- GPRASP1 | c.1355G>A p.S452N | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.377); catalogued as COSV64356126; called by muse, mutect2, varscan2
- GRINA | c.72del p.Q26Sfs*142 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs781965675; called by mutect2, varscan2
- GSDME | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 89/234 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61652417; called by muse, mutect2, varscan2
- GSK3A | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55900145; called by muse, mutect2, varscan2
- GTPBP10 | c.926dup p.N309Kfs*37 | Frame Shift Ins (INS) | VAF 68/190 reads (36%) | catalogued as rs745885335; called by mutect2, varscan2
- H1-4 | c.136A>G p.K46E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.246); catalogued as rs778623700, COSV56802526; called by muse, mutect2, varscan2
- H2BC10 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 18/343 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV100010408, COSV59952776, COSV59953804; called by muse, mutect2
- HDHD5 | c.314C>T p.A105V (on ENST00000336737 / NM_033070.3; = p.A75V on NM_017829.5) | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV50089255; called by muse, mutect2
- HERPUD1 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 18/387 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as COSV55862791; called by muse, mutect2
- HNRNPM | c.283G>T p.V95F | Missense Mutation (SNP) | VAF 55/260 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57693471; called by muse, mutect2, varscan2
- HPN | c.967A>G p.N323D | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52884806; called by muse, mutect2, varscan2
- HSD17B3 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 199/606 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64557795; called by muse, mutect2, varscan2
- HUWE1 | c.11439C>A p.D3813E | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); catalogued as COSV53355741; called by muse, mutect2, varscan2
- HYAL3 | c.409G>T p.G137W | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV56498734; called by muse, mutect2, varscan2
- IDH3G | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.723); catalogued as rs370866394, COSV54207202; called by muse, mutect2, varscan2
- IFNL2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.152); catalogued as rs747844205, COSV59593802; called by muse, mutect2, varscan2
- IGFLR1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1262642786, COSV53075805; called by muse, mutect2, varscan2
- IGSF21 | c.1331A>G p.N444S | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); catalogued as rs750702771, COSV52138847; called by muse, mutect2, varscan2
- IGSF22 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs778827596, COSV60036519; called by muse, mutect2, varscan2
- IGSF9 | c.1915del p.V639Yfs*114 (on ENST00000368094 / NM_001135050.2; = p.V623Yfs*114 on NM_020789.4) | Frame Shift Del (DEL) | VAF 103/312 reads (33%) | catalogued as COSV63641012; called by mutect2, pindel, varscan2
- IMPACT | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV52422779; called by muse, mutect2, varscan2
- IQSEC1 | c.944del p.P315Lfs*218 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as COSV99832030; called by mutect2, varscan2
- ITPKB | c.1346C>T p.T449M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as rs749765819, COSV55265806; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 31/111 reads (28%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- JPT2 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376563287, COSV50189172; called by muse, mutect2
- JPT2 | c.508C>G p.R170G | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50189179; called by muse, mutect2
- KANK1 | c.2968G>A p.A990T | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs138899296; called by muse, mutect2, varscan2
- KATNAL2 | c.1436C>A p.P479H (on ENST00000356157 / NM_001353899.1; = p.P407H on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs370484224; called by muse, mutect2, varscan2
- KCNN2 | c.1670G>A p.R557Q (on ENST00000264773; = p.R769Q on NM_021614.4) | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.921); catalogued as rs772419723, COSV53294015; called by muse, mutect2, varscan2
- KCNS2 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as rs138992941; called by muse, mutect2, varscan2
- KCTD10 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs751042686, COSV57325838; called by muse, mutect2, varscan2
- KDM4C | c.2249C>T p.A750V | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs577091363, COSV67189091; called by muse, mutect2, varscan2
- KERA | c.725del p.L242* | Frame Shift Del (DEL) | VAF 87/318 reads (27%) | catalogued as rs1565745409; called by mutect2, pindel, varscan2
- KIAA0100 | c.1895G>A p.C632Y | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.794); catalogued as COSV66494935; called by muse, mutect2, varscan2
- KLF1 | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV53434508, COSV53435613; called by muse, mutect2, varscan2
- KLHL25 | c.1040del p.G347Afs*29 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | catalogued as rs760548052, COSV100563595; called by mutect2, pindel, varscan2
- KRTAP10-4 | c.1061G>A p.C354Y | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs370084239; called by muse, mutect2, varscan2
- LATS2 | c.2908C>A p.H970N | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66877809; called by muse, mutect2, varscan2
- LENG8 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV58729100; called by muse, mutect2, varscan2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 176/524 reads (34%) | catalogued as rs765287063; called by mutect2, varscan2
- LMBR1 | c.1108C>T p.R370* | Nonsense Mutation (SNP) | VAF 9/233 reads (4%) | catalogued as rs1263101718, COSV62221251; called by muse, mutect2
- LONRF3 | c.1717C>T p.H573Y (on ENST00000371628 / NM_001031855.3; = p.H532Y on NM_024778.5) | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59154863; called by muse, mutect2, varscan2
- LRP1 | c.6524G>A p.R2175H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs778549302, COSV54518627; called by muse, mutect2, varscan2
- LRP12 | c.1351del p.C451Afs*37 | Frame Shift Del (DEL) | VAF 44/164 reads (27%) | catalogued as rs35928649; called by mutect2, varscan2
- LRP2 | c.10925G>A p.C3642Y | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55557887; called by muse, mutect2, varscan2
- LRRFIP1 | c.676G>A p.A226T (on ENST00000392000 / NM_001137552.2; = p.A202T on NM_004735.4) | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.86); catalogued as rs946752164, COSV55253942; called by muse, mutect2, varscan2
- LRRTM1 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as COSV54444255; called by muse, mutect2, varscan2
- LYST | c.7462A>G p.I2488V | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV67710492; called by muse, mutect2
- MAGI1 | c.4213C>T p.R1405C | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.319); catalogued as rs1435154802, COSV58335253; called by muse, mutect2, varscan2
- MAMSTR | c.1141G>A p.G381R (on ENST00000318083 / NM_001130915.2; = p.G278R on NM_182574.2) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV58882290; called by muse, mutect2, varscan2
- MAP3K1 | c.816_817del p.R273Sfs*27 | Frame Shift Del (DEL) | VAF 28/107 reads (26%) | catalogued as COSV68124420; called by mutect2, pindel, varscan2
- MAP3K8 | c.1346G>C p.G449A | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53920736; called by muse, mutect2, varscan2
- MAPKAPK3 | c.1026G>A p.M342I | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV63597965; called by muse, mutect2, varscan2
- MCHR1 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.718); catalogued as rs915365004, COSV50762128; called by muse, mutect2, varscan2
- MDH2 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59884747; called by muse, mutect2, varscan2
- MED1 | c.1709del p.G570Vfs*9 | Frame Shift Del (DEL) | VAF 32/124 reads (26%) | catalogued as COSV56128100; called by mutect2, pindel, varscan2
- MED26 | c.651C>A p.H217Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs1246628526, COSV54661718; called by muse, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- MGST3 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV63321432; called by muse, mutect2, varscan2
- MKI67 | c.698del p.N233Mfs*12 | Frame Shift Del (DEL) | VAF 40/112 reads (36%) | catalogued as rs749903408; called by mutect2, varscan2
- MOAP1 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as rs1263280124, COSV52093035, COSV99365799; called by muse, mutect2, varscan2
- MROH9 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 80/232 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs750550050, COSV63010911; called by muse, mutect2, varscan2
- MSI2 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as rs1409691153, COSV52363222; called by muse, mutect2, varscan2
- MTERF4 | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs763068285, COSV54090193; called by muse, mutect2, varscan2
- MTR | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as rs1382616664, COSV63968870, COSV63969199; called by muse, mutect2, varscan2
- MUC17 | c.12161C>T p.P4054L | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.626); catalogued as rs200510400, COSV60296071; called by muse, mutect2, varscan2
- MYBPH | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs766838702, COSV55143377; called by muse, mutect2, varscan2
- MYH10 | c.399T>G p.I133M | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52605916; called by muse, mutect2, varscan2
- MYH8 | c.4903G>A p.A1635T | Missense Mutation (SNP) | VAF 148/447 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV67969055; called by muse, mutect2, varscan2
- MYO15A | c.4987G>A p.D1663N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876657899, COSV52760972; ClinVar: uncertain significance; called by muse, mutect2
- MYO5B | c.3953A>T p.E1318V | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV53224745; called by muse, mutect2, varscan2
- MYO9B | c.4714G>A p.V1572I | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as rs766634031, COSV68281126; called by muse, mutect2
- NAA30 | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs962373849, COSV53648482; called by muse, mutect2, varscan2
- NASP | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV63113888; called by muse, mutect2, varscan2
- NAT1 | c.347G>A p.G116D | Missense Mutation (SNP) | VAF 151/406 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.22); catalogued as COSV56985906; called by muse, mutect2, varscan2
- NBAS | c.6508G>A p.E2170K | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.83); PolyPhen benign (0.014); catalogued as rs202242469, COSV55730047; called by muse, mutect2, varscan2
- NCDN | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV61936311; called by muse, mutect2, varscan2
- NDUFA10 | c.604del p.H202Tfs*3 | Frame Shift Del (DEL) | VAF 63/207 reads (30%) | catalogued as rs746019378; ClinVar: uncertain significance; called by mutect2, varscan2
- NEK11 | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV63582426; called by muse, mutect2, varscan2
- NEURL4 | c.3799del p.V1267* | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs1202163680; called by mutect2, pindel, varscan2
- NF1 | c.2972T>A p.M991K | Missense Mutation (SNP) | VAF 127/390 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV62211502; called by muse, mutect2, varscan2
- NFASC | c.3581A>G p.Y1194C (on ENST00000339876 / NM_001378329.1; = p.Y1123C on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1558490559, COSV58372621; called by muse, mutect2, varscan2
- NFATC2IP | c.427C>A p.L143I | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV57910743; called by muse, mutect2, varscan2
- NFATC3 | c.1471C>T p.R491* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | catalogued as COSV60476599; called by muse, mutect2, varscan2
- NFIC | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59410866; called by muse, mutect2, varscan2
- NFYA | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774868192, COSV58199242; called by muse, mutect2, varscan2
- NID2 | c.1885A>G p.I629V | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.361); catalogued as rs768552819, COSV53499782; called by muse, mutect2, varscan2
- NISCH | c.3621G>A p.W1207* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV58740107; called by muse, mutect2, varscan2
- NKTR | c.4234C>T p.R1412W | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs745912907, COSV51772122; called by muse, mutect2, varscan2
- NMNAT3 | c.190C>T p.R64* (on ENST00000296202 / NM_001320512.1; = p.R27* on NM_178177.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as rs201923390, COSV56155493, COSV56156281; called by muse, mutect2
- NOL3 | c.620-1G>A p.X207_splice | Splice Site (SNP) | VAF 19/436 reads (4%) | catalogued as COSV51783686; called by muse, mutect2
- NOS1 | c.2986C>T p.R996* | Nonsense Mutation (SNP) | VAF 64/203 reads (32%) | catalogued as COSV57608407; called by muse, mutect2, varscan2
- NOTCH3 | c.5338A>G p.M1780V | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs760675309, COSV54641607; called by muse, mutect2, varscan2
- NOXRED1 | c.100A>G p.M34V | Missense Mutation (SNP) | VAF 19/322 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.122); catalogued as rs774106739, COSV53628648; called by muse, mutect2
- NRBP1 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 30/448 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV51995075; called by muse, mutect2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 60/160 reads (38%) | catalogued as rs776154715; called by mutect2, varscan2
- NRIP1 | c.748del p.R250Gfs*17 | Frame Shift Del (DEL) | VAF 72/255 reads (28%) | catalogued as COSV100012815; called by mutect2, pindel, varscan2
- NRP1 | c.1718G>A p.G573E | Missense Mutation (SNP) | VAF 86/255 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55171952; called by muse, varscan2
- NRP1 | c.973T>A p.W325R | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55171994; called by muse, mutect2, varscan2
- NSD1 | c.3205C>T p.Q1069* | Nonsense Mutation (SNP) | VAF 97/319 reads (30%) | catalogued as COSV61773880, COSV61779841; called by muse, mutect2, varscan2
- NSD1 | c.6380C>T p.A2127V | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV61779849; called by muse, mutect2, varscan2
- NSMCE1 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376178703; called by muse, mutect2, varscan2
- NTAN1 | c.831del p.K277Nfs*83 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | catalogued as COSV55073962; called by mutect2, pindel, varscan2
- NUMA1 | c.4039C>T p.Q1347* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV61188253; called by muse, mutect2, varscan2
- NUP160 | c.3415T>C p.Y1139H | Missense Mutation (SNP) | VAF 116/290 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV65855111; called by muse, mutect2, varscan2
- ODF4 | c.454+2T>C p.X152_splice | Splice Site (SNP) | VAF 14/41 reads (34%) | catalogued as COSV60272472; called by muse, mutect2, varscan2
- OGDH | c.1649T>A p.V550D | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56053697; called by muse, mutect2, varscan2
- OR1E2 | c.312_314del p.F104del | In Frame Del (DEL) | VAF 62/263 reads (24%) | catalogued as rs767081414; called by pindel, varscan2
- OR2F2 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 114/289 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68833075; called by muse, mutect2, varscan2
- OR2T35 | c.761C>A p.A254E | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1454777634, COSV58086735; called by muse, mutect2
- OR4K2 | c.187C>A p.L63I | Missense Mutation (SNP) | VAF 140/712 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV53850698; called by muse, mutect2, varscan2
- OR51F2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 88/938 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.034); catalogued as COSV59065447; called by muse, mutect2
- OR52M1 | c.433C>G p.R145G | Missense Mutation (SNP) | VAF 80/211 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as rs267602886, COSV64172059; called by muse, mutect2, varscan2
- OR52N2 | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV57677360; called by muse, mutect2, varscan2
- OR5B12 | c.597del p.F199Lfs*13 | Frame Shift Del (DEL) | VAF 72/195 reads (37%) | catalogued as rs747074822; called by mutect2, varscan2
- OSER1 | c.27G>T p.E9D | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as COSV54854217; called by muse, mutect2, varscan2
- OSMR | c.1849del p.T617Qfs*20 | Frame Shift Del (DEL) | VAF 49/162 reads (30%) | catalogued as rs762315064; called by mutect2, pindel, varscan2
- OXR1 | c.1369A>T p.N457Y (on ENST00000442977 / NM_001198532.1; = p.N456Y on NM_018002.3) | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.169); catalogued as COSV56333186; called by muse, mutect2, varscan2
- P3H2 | c.1922T>C p.M641T | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); catalogued as COSV60024631; called by muse, mutect2, varscan2
- PATJ | c.4810C>T p.Q1604* | Nonsense Mutation (SNP) | VAF 35/96 reads (36%) | catalogued as COSV57167022; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PAX6 | c.659A>G p.E220G | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV53794685; called by muse, mutect2, varscan2
- PCDH10 | c.1993C>T p.Q665* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV52099228; called by muse, mutect2, varscan2
- PCDH10 | c.3122A>G p.*1041Wext*11 | Nonstop Mutation (SNP) | VAF 28/72 reads (39%) | catalogued as COSV52099238; called by muse, mutect2, varscan2
- PCDHA12 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.116); catalogued as COSV56494202; called by muse, mutect2, varscan2
- PCDHA9 | c.2278T>A p.S760T | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.142); catalogued as COSV65329600; called by muse, mutect2, varscan2
- PCDHGB4 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV53989055; called by muse, mutect2, varscan2
- PCED1B | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV71394983; called by muse, mutect2, varscan2
- PCLO | c.14595G>T p.K4865N | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61650275; called by muse, mutect2, varscan2
- PDE4DIP | c.742del p.I248Sfs*18 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as rs781818141; called by mutect2, varscan2
- PDLIM4 | c.400G>T p.G134* | Nonsense Mutation (SNP) | VAF 59/174 reads (34%) | catalogued as COSV53804817; called by muse, mutect2, varscan2
- PDLIM5 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 67/191 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV58750144; called by muse, mutect2, varscan2
- PEDS1 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs768840504, COSV59014209; called by muse, mutect2, varscan2
- PEG3 | c.2990C>T p.S997F | Missense Mutation (SNP) | VAF 98/254 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.407); catalogued as COSV55640521; called by muse, varscan2
- PIGH | c.474G>T p.Q158H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV53614770; called by muse, mutect2, varscan2
- PIGS | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs763402672, COSV52025511; called by muse, mutect2, varscan2
- PIK3R1 | c.1347_1367delinsGAAACA p.H450_F456delinsKH (on ENST00000521381 / NM_181523.3; = p.H180_F186delinsKH on NM_181504.4) | In Frame Del (DEL) | VAF 26/86 reads (30%) | catalogued as COSV57122790; called by pindel, varscan2*
- PIK3R1 | c.1393_1409del p.R465Yfs*15 (on ENST00000521381 / NM_181523.3; = p.R195Yfs*15 on NM_181504.4) | Frame Shift Del (DEL) | VAF 30/104 reads (29%) | catalogued as COSV57134573; called by pindel, varscan2
- PIK3R5 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.083); catalogued as rs369083136; called by muse, mutect2, varscan2
- PISD | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs577732740, COSV60673801; called by muse, mutect2
- PLA2G2F | c.566G>A p.S189N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs768632087, COSV64280178; called by muse, mutect2, varscan2
- PLCE1 | c.6502-1G>A p.X2168_splice | Splice Site (SNP) | VAF 97/257 reads (38%) | catalogued as COSV53361118; called by muse, mutect2, varscan2
- PLCG1 | c.3821G>A p.R1274Q (on ENST00000373271 / NM_182811.2; = p.R1275Q on NM_002660.3) | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs372257814; called by muse, mutect2, varscan2
- PLIN3 | c.659G>A p.G220D | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV55734533, COSV55736118; called by muse, mutect2, varscan2
- PLOD3 | c.876del p.Q293Sfs*65 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs746342377, COSV56183473; called by mutect2, pindel, varscan2
- POLR2A | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 22/95 reads (23%) | catalogued as rs767064007, COSV59494125; called by muse, mutect2, varscan2
- PPIL3 | c.91C>A p.L31I | Missense Mutation (SNP) | VAF 74/228 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53769812; called by muse, mutect2, varscan2
- PPRC1 | c.4579T>C p.Y1527H | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV53387129; called by muse, mutect2, varscan2
- PRDM1 | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.346); catalogued as rs548489075, COSV64846037; ClinVar: not provided; called by muse, mutect2, varscan2
- PRDX3 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs751585321, COSV53720127; called by muse, mutect2, varscan2
- PRKCG | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54730333; called by muse, mutect2
- PRKDC | c.7664del p.L2555* | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | catalogued as rs34870758; called by mutect2, pindel, varscan2
- PRR5L | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.099); catalogued as rs150643262, COSV61122549; called by muse, mutect2, varscan2
- PRRC2A | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs750688400, COSV63224864; called by muse, mutect2, varscan2
- PRRC2A | c.5090C>A p.P1697H | Missense Mutation (SNP) | VAF 86/194 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.428); catalogued as COSV52988255, COSV52993074; called by muse, mutect2, varscan2
- PRSS21 | c.410A>G p.D137G | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50051806; called by muse, mutect2, varscan2
- PSMC2 | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV53008364; called by muse, mutect2, varscan2
- PTEN | c.433T>A p.F145I | Missense Mutation (SNP) | VAF 120/348 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64292458; called by muse, mutect2, varscan2
- PTPN9 | c.1339C>G p.L447V | Missense Mutation (SNP) | VAF 110/317 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV60724898; called by muse, mutect2, varscan2
- PTPRN | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV55350323; called by muse, mutect2, varscan2
- PTPRU | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.361); catalogued as COSV60532428; called by muse, mutect2, varscan2
- PVRIG | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV52781960, COSV99443718; called by muse, mutect2, varscan2
- RAX | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768555667, COSV56874970; called by muse, mutect2, varscan2
- RBL1 | c.2782G>T p.G928C | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60331452; called by muse, mutect2
- RBM42 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV52898388; called by muse, mutect2, varscan2
- RBP5 | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV56938540; called by muse, mutect2, varscan2
- RECK | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 84/260 reads (32%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.979); catalogued as COSV65035856; called by muse, mutect2, varscan2
- RHOQ | c.577dup p.R193Kfs*32 | Frame Shift Ins (INS) | VAF 33/120 reads (28%) | catalogued as rs1368074831; called by mutect2, varscan2
- RND1 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.983); catalogued as COSV59045751; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPRD1B | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV65033549; called by muse, mutect2, varscan2
- S1PR3 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs778339232, COSV63980955; called by muse, mutect2, varscan2
- SAMD14 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.104); catalogued as rs749565302, COSV50304274; called by muse, mutect2, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 46/190 reads (24%) | catalogued as COSV54589079; called by mutect2, pindel, varscan2
- SCN11A | c.4954G>A p.A1652T | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.13); catalogued as COSV56571676; called by muse, mutect2, varscan2
- SDK1 | c.5632C>T p.R1878C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs763370088, COSV67379777; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 36/100 reads (36%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA7A | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.254); catalogued as COSV56091322; called by muse, mutect2, varscan2
- SESN2 | c.722del p.P241Qfs*6 | Frame Shift Del (DEL) | VAF 14/63 reads (22%) | catalogued as rs770146088, COSV53426876; called by mutect2, pindel, varscan2
- SESN3 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs542136270, COSV53585125; called by muse, mutect2, varscan2
- SETX | c.3872del p.K1291Rfs*17 | Frame Shift Del (DEL) | VAF 144/517 reads (28%) | catalogued as COSV56387007; called by mutect2, pindel, varscan2
- SF3B2 | c.2625dup p.R876Tfs*16 | Frame Shift Ins (INS) | VAF 32/82 reads (39%) | catalogued as rs759211171; called by mutect2, varscan2
- SFTPD | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV64853466; called by muse, mutect2, varscan2
- SH3D21 | c.1818del p.N607Tfs*6 (on ENST00000453908 / NM_001162530.2; = p.N496Tfs*6 on NM_024676.5) | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | catalogued as rs774514258; called by mutect2, pindel, varscan2
- SH3RF2 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs566012144, COSV63038623; called by muse, mutect2, varscan2
- SHANK2 | c.2399G>T p.R800L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53609142, COSV53625054; called by muse, mutect2, varscan2
- SHLD1 | c.85T>C p.Y29H | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.776); catalogued as rs1191894322, COSV57437978; called by muse, mutect2, varscan2
- SHOC1 | c.4318C>T p.R1440W | Missense Mutation (SNP) | VAF 75/220 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs547213345, COSV59504514; called by muse, mutect2, varscan2
- SIGLEC1 | c.4291C>A p.L1431M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV52468152; called by muse, mutect2, varscan2
- SIGLEC15 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as rs764771452, COSV67181286; called by muse, mutect2, varscan2
- SLC14A2 | c.166A>C p.N56H | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.438); catalogued as COSV54911498; called by muse, mutect2, varscan2
- SLC22A6 | c.777del p.F259Lfs*27 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | catalogued as rs749849908; called by mutect2, pindel, varscan2
- SLC24A1 | c.2716C>T p.Q906* | Nonsense Mutation (SNP) | VAF 52/147 reads (35%) | catalogued as COSV56053051; called by muse, mutect2, varscan2
- SLC26A5 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 96/297 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.545); catalogued as rs760928224, COSV59703928; called by muse, mutect2, varscan2
- SLC26A7 | c.1046T>C p.L349P | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52599217; called by muse, mutect2, varscan2
- SLC30A7 | c.878T>C p.L293S | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63018165; called by muse, mutect2, varscan2
- SLC35A5 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs866537161, COSV53727461; called by muse, mutect2, varscan2
- SLC35D2 | c.478A>G p.I160V | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs894564109, COSV53563819; called by muse, mutect2, varscan2
- SLC7A13 | c.372del p.S126Afs*20 | Frame Shift Del (DEL) | VAF 69/212 reads (33%) | catalogued as COSV52536834; called by mutect2, pindel, varscan2
- SLF1 | c.2161C>T p.L721F | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.04); catalogued as COSV54371821; called by muse, mutect2, varscan2
- SLFNL1 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.637); catalogued as rs367658059; called by muse, mutect2, varscan2
- SMC5 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 81/239 reads (34%) | catalogued as COSV63194295; called by muse, mutect2, varscan2
- SMCHD1 | c.4651A>G p.T1551A | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV55263025; called by muse, mutect2
- SND1 | c.2240G>A p.R747H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61235186; called by muse, mutect2, varscan2
- SNTG2 | c.1083G>A p.W361* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as rs1265025119, COSV57995880; called by muse, mutect2, varscan2
- SP140 | c.2015del p.K672Rfs*4 | Frame Shift Del (DEL) | VAF 34/96 reads (35%) | catalogued as rs746109620; called by mutect2, varscan2
- SPAG17 | c.337A>G p.I113V | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs757187513, COSV60463355; called by muse, mutect2, varscan2
- SPANXN3 | c.71dup p.N24Kfs*2 | Frame Shift Ins (INS) | VAF 106/312 reads (34%) | catalogued as rs781940283; called by mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 106/283 reads (37%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPEN | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV65364970, COSV65364998; called by muse, mutect2, varscan2
- SRARP | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs752364803, COSV61497896; called by muse, mutect2, varscan2
- SRCAP | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 100/311 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.1); catalogued as COSV52676971; called by muse, mutect2, varscan2
- SREK1IP1 | c.271del p.R91Gfs*67 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | catalogued as rs750306056; called by mutect2, varscan2
- SSX5 | c.407G>A p.G136E (on ENST00000347757 / NM_175723.1; = p.G177E on NM_021015.4) | Missense Mutation (SNP) | VAF 142/417 reads (34%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.796); catalogued as COSV61255884; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214dup p.F407Lfs*55 | Frame Shift Ins (INS) | VAF 24/74 reads (32%) | catalogued as rs752994755; called by mutect2, varscan2
- STK4 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 99/267 reads (37%) | catalogued as rs749441226, CM162868, COSV65671172; called by muse, mutect2, varscan2
- STMN4 | c.97T>C p.Y33H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV56109601; called by muse, mutect2, varscan2
- SV2A | c.412del p.E138Rfs*39 | Frame Shift Del (DEL) | VAF 56/177 reads (32%) | catalogued as rs1553764068; called by mutect2, pindel, varscan2
- SV2C | c.664C>A p.L222M | Missense Mutation (SNP) | VAF 127/389 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.574); catalogued as COSV59224720; called by muse, mutect2, varscan2
- SYCP2 | c.2362dup p.M788Nfs*23 | Frame Shift Ins (INS) | VAF 79/232 reads (34%) | catalogued as rs570102997; called by mutect2, varscan2
- SYDE2 | c.667T>C p.S223P | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV52316778; called by mutect2, varscan2
- SYNE1 | c.8458C>T p.Q2820* (on ENST00000367255 / NM_182961.4; = p.Q2827* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 95/249 reads (38%) | catalogued as COSV55038914; called by muse, mutect2, varscan2
- SYNE2 | c.1663A>G p.N555D | Missense Mutation (SNP) | VAF 26/431 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV59959475; called by muse, mutect2
- SYNGAP1 | c.134A>G p.N45S | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.678); catalogued as COSV53383910; called by muse, mutect2, varscan2
- SYNPR | c.30del p.F10Lfs*18 | Frame Shift Del (DEL) | VAF 98/337 reads (29%) | catalogued as COSV99888757; called by mutect2, pindel, varscan2
- TAF1D | c.281del p.K94Rfs*26 | Frame Shift Del (DEL) | VAF 109/302 reads (36%) | catalogued as rs746556335; called by mutect2, varscan2
- TAS2R30 | c.608G>A p.C203Y | Missense Mutation (SNP) | VAF 42/617 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV67859293; called by muse, mutect2
- TBCEL | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV52461092; called by muse, mutect2
- TENM1 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 119/622 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.557); catalogued as COSV64437711; called by muse, mutect2, varscan2
- TEX15 | c.6724A>G p.I2242V (on ENST00000256246; = p.I2625V on NM_001350162.2) | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV56349975; called by muse, mutect2
- TGFBRAP1 | c.614G>A p.C205Y | Missense Mutation (SNP) | VAF 80/263 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.288); catalogued as rs777441462, COSV51514314; called by muse, mutect2, varscan2
- TGIF1 | c.31G>A p.A11T (on ENST00000330513 / NM_001374396.1; = p.A31T on NM_003244.4) | Missense Mutation (SNP) | VAF 132/399 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs371311801, CM109681, COSV57908699; called by muse, mutect2, varscan2
- TIGD3 | c.258G>T p.W86C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52890495; called by muse, mutect2, varscan2
- TIMM44 | c.312C>T p.Y104= | Splice Region (SNP) | VAF 52/142 reads (37%) | catalogued as rs746616577, COSV54493057; called by muse, mutect2, varscan2
- TMC7 | c.962G>A p.S321N | Missense Mutation (SNP) | VAF 75/200 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58585575; called by muse, mutect2, varscan2
- TMEM17 | c.39C>A p.N13K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.245); catalogued as COSV59023025; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 64/187 reads (34%) | catalogued as rs749773249; called by mutect2, varscan2
- TMEM63A | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1274492466, COSV64763642; called by muse, mutect2, varscan2
- TNFRSF10B | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs571677132, COSV52393403; called by muse, varscan2
- TNFRSF9 | c.345del p.G116Vfs*33 | Frame Shift Del (DEL) | VAF 56/201 reads (28%) | catalogued as rs752649731; called by mutect2, pindel, varscan2
- TOGARAM1 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV61888842; called by muse, mutect2, varscan2
- TOMM70 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 75/196 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs376877331; called by muse, mutect2, varscan2
- TRIM39-RPP21 | c.1169C>T p.T390I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); catalogued as COSV64954962; called by muse, mutect2, varscan2
- TRPC3 | c.488C>T p.T163I (on ENST00000379645 / NM_001366479.2; = p.T90I on NM_003305.2) | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.279); catalogued as COSV53378256; called by muse, mutect2, varscan2
- TSN | c.524A>G p.N175S | Missense Mutation (SNP) | VAF 32/534 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.027); catalogued as rs774578869, COSV67605500; called by muse, mutect2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 88/338 reads (26%) | catalogued as rs756650873; called by mutect2, varscan2
- TTN | c.61550G>A p.G20517D (on ENST00000591111; = p.G13093D on NM_003319.4) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | PolyPhen probably damaging (1); catalogued as COSV60198162; called by muse, mutect2, varscan2
- TTN | c.41249C>T p.T13750I (on ENST00000591111; = p.T6326I on NM_003319.4) | Missense Mutation (SNP) | VAF 16/206 reads (8%) | PolyPhen possibly damaging (0.813); catalogued as rs775807236, COSV60198189; ClinVar: uncertain significance; called by muse, mutect2
- TUBA1B | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV60137861; called by muse, mutect2, varscan2
- TUBB4B | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.094); catalogued as COSV61118078; called by muse, mutect2, varscan2
- TULP1 | c.901del p.Q301Rfs*9 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs62636292, CD004592, CM098172; ClinVar: not provided; called by mutect2, pindel, varscan2
- TVP23A | c.110del p.F37Sfs*7 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs758470373; called by mutect2, pindel, varscan2
- UHRF1BP1L | c.1805T>C p.I602T | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV54439904; called by muse, mutect2, varscan2
- URI1 | c.476T>C p.V159A | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV56351644; called by muse, mutect2, varscan2
- UROC1 | c.1095G>T p.Q365H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as COSV52036072; called by muse, mutect2, varscan2
- USP13 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs773295364, COSV55865334; called by muse, mutect2, varscan2
- USP32 | c.2186C>T p.T729I | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV56272675; called by muse, mutect2, varscan2
- VCP | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.801); catalogued as COSV62721394; called by muse, varscan2
- VPS18 | c.1171G>A p.V391M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs202222195, COSV55029497; called by muse, mutect2, varscan2
- VPS33A | c.1376del p.G459Afs*86 | Frame Shift Del (DEL) | VAF 63/195 reads (32%) | catalogued as rs1357715083, COSV57357082; called by mutect2, pindel, varscan2
- VPS41 | c.1163del p.N388Ifs*15 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | catalogued as rs757692785; called by mutect2, pindel, varscan2
- VPS8 | c.4141G>A p.A1381T (on ENST00000625842 / NM_001349294.1; = p.A1379T on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.388); catalogued as COSV54991251; called by muse, mutect2, varscan2
- WASHC2A | c.2812-1G>T p.X938_splice | Splice Site (SNP) | VAF 167/816 reads (20%) | catalogued as rs1387222481; called by muse, mutect2, varscan2
- WDFY3 | c.8768C>T p.A2923V | Missense Mutation (SNP) | VAF 97/246 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.428); catalogued as COSV55708350; called by muse, mutect2, varscan2
- WNK4 | c.1849C>A p.L617I | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV55907678; called by muse, mutect2, varscan2
- XCR1 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.08); catalogued as rs751147788, COSV58570104; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 41/104 reads (39%) | catalogued as rs762052135; called by mutect2, varscan2
- XXYLT1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs779456915, COSV59986124; called by muse, mutect2, varscan2
- ZC3H13 | c.3421G>A p.A1141T | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs915180469, COSV54458977; called by muse, mutect2, varscan2
- ZC3H3 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs745628585, COSV52792383; called by muse, mutect2, varscan2
- ZMYM4 | c.3665del p.N1222Mfs*9 | Frame Shift Del (DEL) | VAF 80/267 reads (30%) | catalogued as COSV104406282; called by mutect2, pindel, varscan2
- ZMYM5 | c.1934del p.N645Ifs*56 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs746181263; called by mutect2, varscan2
- ZNF132 | c.1072A>G p.N358D | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.584); catalogued as COSV54235506; called by muse, mutect2, varscan2
- ZNF432 | c.1088A>G p.H363R | Missense Mutation (SNP) | VAF 130/348 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772975063, COSV55417642; called by muse, mutect2, varscan2
- ZNF512 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62677058; called by muse, mutect2, varscan2
- ZNF547 | c.24G>A p.Q8= | Splice Region (SNP) | VAF 46/127 reads (36%) | catalogued as COSV56581316; called by muse, mutect2, varscan2
- ZNF564 | c.68C>A p.P23H | Missense Mutation (SNP) | VAF 19/275 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV59435075, COSV59435823; called by muse, mutect2
- ZNF584 | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59722942; called by muse, mutect2, varscan2
- ZNF653 | c.1226C>G p.P409R | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV53402612, COSV53403922; called by muse, mutect2, varscan2
- ZNF830 | c.753del p.F251Lfs*6 | Frame Shift Del (DEL) | VAF 40/108 reads (37%) | catalogued as rs749765261; called by mutect2, pindel, varscan2
- ZNF839 | c.728G>A p.C243Y (on ENST00000558850 / NM_001267827.1; = p.C359Y on NM_018335.5) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.693); catalogued as rs370145192; called by muse, mutect2, varscan2
- ZXDB | c.2219C>T p.S740L | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66493114; called by muse, mutect2
- ZZEF1 | c.6431T>A p.I2144N | Missense Mutation (SNP) | VAF 106/282 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV67558883; called by muse, mutect2, varscan2
- AMPD1 | c.839del p.L280Yfs*4 | Frame Shift Del (DEL) | VAF 49/198 reads (25%) | called by mutect2, pindel, varscan2
- ANKRD26 | c.3702del p.K1234Nfs*19 | Frame Shift Del (DEL) | VAF 132/439 reads (30%) | called by mutect2, pindel, varscan2
- ARHGEF12 | c.48dup p.P17Tfs*16 | Frame Shift Ins (INS) | VAF 36/129 reads (28%) | called by mutect2, pindel, varscan2
- ARID4B | c.3434del p.K1145Rfs*20 | Frame Shift Del (DEL) | VAF 88/277 reads (32%) | called by mutect2, pindel, varscan2
- ASPM | c.7649del p.L2550* | Frame Shift Del (DEL) | VAF 40/132 reads (30%) | called by mutect2, pindel, varscan2
- ATAD2B | c.1512del p.F504Lfs*4 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- ATRIP | c.1033del p.L345Cfs*31 | Frame Shift Del (DEL) | VAF 29/102 reads (28%) | called by mutect2, pindel, varscan2
- BSCL2 | c.782del p.G261Afs*75 | Frame Shift Del (DEL) | VAF 35/104 reads (34%) | called by mutect2, pindel, varscan2
- C1RL | c.1051del p.L351Wfs*35 | Frame Shift Del (DEL) | VAF 28/96 reads (29%) | called by mutect2, pindel, varscan2
- CDKL5 | c.1227del p.E410Kfs*83 | Frame Shift Del (DEL) | VAF 228/730 reads (31%) | called by mutect2, pindel, varscan2
- CDKN2AIP | c.559_560del p.S187Wfs*14 | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | called by pindel, varscan2
- CENPN | c.92del p.L31Cfs*9 | Frame Shift Del (DEL) | VAF 25/88 reads (28%) | called by mutect2, pindel, varscan2
- CENPS-CORT | c.479_481del p.F160del | In Frame Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel
- CFAP36 | c.726del p.D243Tfs*2 | Frame Shift Del (DEL) | VAF 81/222 reads (36%) | called by mutect2, varscan2
- CILK1 | c.662del p.K221Rfs*14 | Frame Shift Del (DEL) | VAF 155/542 reads (29%) | called by mutect2, pindel, varscan2
- COL18A1 | c.2082del p.V695Sfs*29 (on ENST00000359759 / NM_130444.3; = p.V460Sfs*29 on NM_030582.4) | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- COL4A5 | c.4819del p.A1607Qfs*8 | Frame Shift Del (DEL) | VAF 112/374 reads (30%) | called by mutect2, pindel, varscan2
- CRTC2 | c.262del p.L88Sfs*92 | Frame Shift Del (DEL) | VAF 42/161 reads (26%) | called by mutect2, pindel, varscan2
- DENND4B | c.794del p.G265Vfs*34 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- DNAH11 | c.12824del p.N4275Ifs*18 | Frame Shift Del (DEL) | VAF 63/208 reads (30%) | called by mutect2, pindel, varscan2
- DNAJC6 | c.1589del p.G530Vfs*44 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- DOCK9 | c.4880del p.N1627Mfs*14 (on ENST00000376460 / NM_001366676.2; = p.N1628Mfs*14 on NM_015296.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel
- EFHC2 | c.1314del p.F438Lfs*4 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | called by mutect2, pindel, varscan2
- ERCC6L2 | c.3335del p.L1112* | Frame Shift Del (DEL) | VAF 31/84 reads (37%) | called by mutect2, pindel, varscan2
- EXOSC10 | c.704del p.P235Lfs*28 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | called by mutect2, pindel, varscan2
- FHDC1 | c.3079dup p.H1027Pfs*219 | Frame Shift Ins (INS) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- FOXM1 | c.2008del p.E671Nfs*12 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | called by mutect2, pindel
- GABRQ | c.1751del p.P584Qfs*109 | Frame Shift Del (DEL) | VAF 60/212 reads (28%) | called by mutect2, pindel, varscan2
- GCC2 | c.2107_2129delinsACAGTTGAGTAGGGATTTGGAGG p.Q703_V710delinsTVE* | Nonsense Mutation (ONP) | VAF 76/710 reads (11%) | called by pindel, varscan2*
- GPLD1 | c.716del p.L239Wfs*26 | Frame Shift Del (DEL) | VAF 38/124 reads (31%) | called by mutect2, pindel, varscan2
- GPR179 | c.6949dup p.S2317Ffs*4 (on ENST00000621958; = p.S2316Ffs*4 on NM_001004334.4) | Frame Shift Ins (INS) | VAF 143/494 reads (29%) | called by mutect2, pindel, varscan2
- HIC2 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.235); called by muse, mutect2
- HIVEP2 | c.5512del p.T1838Rfs*5 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | called by mutect2, pindel, varscan2
- HM13 | c.799_801del p.V267del | In Frame Del (DEL) | VAF 24/70 reads (34%) | called by pindel, varscan2
- IFNLR1 | c.1501del p.A501Lfs*74 | Frame Shift Del (DEL) | VAF 33/124 reads (27%) | called by mutect2, pindel, varscan2
- ILF3 | c.1201del p.Q401Rfs*3 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel
- IMPA1 | c.235del p.S79Vfs*3 | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | called by mutect2, pindel, varscan2
- ING3 | c.632_643del p.Y211_G214del | In Frame Del (DEL) | VAF 49/147 reads (33%) | called by mutect2, pindel, varscan2
- ITGB1 | c.1970dup p.K658Efs*12 | Frame Shift Ins (INS) | VAF 64/208 reads (31%) | called by mutect2, pindel, varscan2
- ITM2B | c.623_640del p.R208_D213del | In Frame Del (DEL) | VAF 52/180 reads (29%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 49/156 reads (31%) | called by mutect2, varscan2
- JARID2 | c.1186del p.A396Rfs*18 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | called by mutect2, pindel, varscan2
- KCTD4 | c.556_558del p.E186del | In Frame Del (DEL) | VAF 50/202 reads (25%) | called by pindel, varscan2
- KLC1 | c.281del p.N94Ifs*3 | Frame Shift Del (DEL) | VAF 33/115 reads (29%) | called by mutect2, pindel, varscan2
- KLHL9 | c.1713del p.D572Mfs*51 | Frame Shift Del (DEL) | VAF 96/279 reads (34%) | called by mutect2, pindel, varscan2
- LAMA2 | c.3837dup p.T1280Dfs*6 | Frame Shift Ins (INS) | VAF 65/245 reads (27%) | called by mutect2, pindel, varscan2
- LIG3 | c.469del p.I157Sfs*21 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by mutect2, varscan2
- LRP1 | c.4468del p.E1490Rfs*80 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- MBD6 | c.2012del p.P671Lfs*4 | Frame Shift Del (DEL) | VAF 4/15 reads (27%) | called by mutect2, varscan2
- MPEG1 | c.1371del p.A458Lfs*31 | Frame Shift Del (DEL) | VAF 44/147 reads (30%) | called by mutect2, pindel, varscan2
- MYH10 | c.4771_4773del p.K1591del | In Frame Del (DEL) | VAF 45/130 reads (35%) | called by pindel, varscan2
- MYRIP | c.1713del p.Q573Rfs*18 | Frame Shift Del (DEL) | VAF 65/208 reads (31%) | called by mutect2, pindel, varscan2
- MYSM1 | c.1701del p.F567Lfs*11 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- NAA25 | c.850_852del p.P284del | In Frame Del (DEL) | VAF 65/255 reads (25%) | called by pindel, varscan2
- NEXMIF | c.625del p.L209Cfs*33 | Frame Shift Del (DEL) | VAF 140/394 reads (36%) | called by mutect2, varscan2
- NOL6 | c.2857del p.Q953Kfs*32 | Frame Shift Del (DEL) | VAF 30/100 reads (30%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.4254del p.S1419Afs*8 | Frame Shift Del (DEL) | VAF 28/95 reads (29%) | called by mutect2, pindel, varscan2
- PEG3 | c.329del p.K110Sfs*29 | Frame Shift Del (DEL) | VAF 37/142 reads (26%) | called by mutect2, pindel, varscan2
- PGLYRP2 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- PHF21B | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- PICALM | c.329dup p.L110Ffs*3 | Frame Shift Ins (INS) | VAF 15/60 reads (25%) | called by mutect2, pindel, varscan2
- PIK3R3 | c.883del p.M295* | Frame Shift Del (DEL) | VAF 79/257 reads (31%) | called by mutect2, pindel, varscan2
- PRB3 | c.812del p.P271Hfs*78 (on ENST00000381842; = p.P313Hfs*? on NM_006249.5) | Frame Shift Del (DEL) | VAF 260/819 reads (32%) | called by mutect2, pindel, varscan2
- PRPF4B | c.2340del p.K780Nfs*13 | Frame Shift Del (DEL) | VAF 46/153 reads (30%) | called by mutect2, pindel, varscan2
- PTEN | c.270del p.F90Lfs*9 | Frame Shift Del (DEL) | VAF 109/342 reads (32%) | called by mutect2, pindel, varscan2
- PTEN | c.867del p.V290* | Frame Shift Del (DEL) | VAF 80/310 reads (26%) | called by mutect2, pindel, varscan2
- RPA2 | c.356_357del p.V119Gfs*26 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | called by pindel, varscan2
- SAMD7 | c.224del p.L75Yfs*6 | Frame Shift Del (DEL) | VAF 47/161 reads (29%) | called by mutect2, pindel, varscan2
- SERPINI2 | c.77del p.N26Ifs*27 | Frame Shift Del (DEL) | VAF 138/374 reads (37%) | called by mutect2, varscan2
- SEZ6L2 | c.1620_1621del p.P541Rfs*7 (on ENST00000308713 / NM_001114099.3; = p.P471Rfs*7 on NM_012410.4) | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | called by pindel, varscan2
- SLIT3 | c.675dup p.L226Afs*64 | Frame Shift Ins (INS) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- SPICE1 | c.1590del p.F530Lfs*7 | Frame Shift Del (DEL) | VAF 56/176 reads (32%) | called by mutect2, pindel, varscan2
- STON1 | c.1072del p.R358Gfs*9 | Frame Shift Del (DEL) | VAF 38/130 reads (29%) | called by mutect2, pindel, varscan2
- SUCNR1 | c.735del p.F245Lfs*10 | Frame Shift Del (DEL) | VAF 106/398 reads (27%) | called by mutect2, pindel, varscan2
- SUCO | c.828_830del p.K277del | In Frame Del (DEL) | VAF 20/66 reads (30%) | called by pindel, varscan2
- TBC1D10B | c.961_962del p.S321Lfs*20 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by pindel, varscan2
- TCP1 | c.1238dup p.A414Cfs*11 | Frame Shift Ins (INS) | VAF 57/178 reads (32%) | called by mutect2, pindel, varscan2
- TENM2 | c.1004del p.P335Rfs*5 (on ENST00000518659 / NM_001122679.2; = p.P144Rfs*5 on NM_001080428.3) | Frame Shift Del (DEL) | VAF 87/280 reads (31%) | called by mutect2, pindel, varscan2
- TMEM168 | c.643dup p.S215Ffs*22 | Frame Shift Ins (INS) | VAF 170/504 reads (34%) | called by mutect2, varscan2
- TNFRSF21 | c.1744_1746del p.K582del | In Frame Del (DEL) | VAF 52/170 reads (31%) | called by pindel, varscan2
- TPP1 | c.496del p.H166Mfs*17 | Frame Shift Del (DEL) | VAF 31/99 reads (31%) | called by mutect2, pindel, varscan2
- TST | c.854del p.P285Qfs*16 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | called by mutect2, pindel
- TTN | c.4691del p.N1564Mfs*4 (on ENST00000591111; = p.N1518Mfs*4 on NM_003319.4) | Frame Shift Del (DEL) | VAF 29/137 reads (21%) | called by mutect2, pindel, varscan2
- UGT8 | c.1421dup p.L474Ffs*36 | Frame Shift Ins (INS) | VAF 99/273 reads (36%) | called by mutect2, varscan2
- VIM | c.590_591dup p.E198Rfs*38 | Frame Shift Ins (INS) | VAF 28/85 reads (33%) | called by mutect2, varscan2
- VPS50 | c.1608_1610del p.E536del | In Frame Del (DEL) | VAF 82/270 reads (30%) | called by pindel, varscan2
- YES1 | c.559_560del p.S187* | Frame Shift Del (DEL) | VAF 24/101 reads (24%) | called by pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 24/78 reads (31%) | called by mutect2, pindel
- ZCWPW1 | c.1459del p.T487Pfs*24 | Frame Shift Del (DEL) | VAF 376/1424 reads (26%) | called by pindel, varscan2
- ZFC3H1 | c.4240del p.R1414Efs*30 | Frame Shift Del (DEL) | VAF 54/225 reads (24%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.4609_4610del p.K1537Vfs*35 | Frame Shift Del (DEL) | VAF 97/340 reads (29%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.2287del p.E763Sfs*61 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- ZHX2 | c.1800dup p.G601Rfs*71 | Frame Shift Ins (INS) | VAF 25/113 reads (22%) | called by mutect2, pindel, varscan2
- ZNF292 | c.4035dup p.D1346Rfs*14 | Frame Shift Ins (INS) | VAF 33/115 reads (29%) | called by mutect2, pindel, varscan2
- ZNF646 | c.2143del p.S715Vfs*123 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | called by mutect2, pindel, varscan2
- ZNFX1 | c.4638_4639del p.C1546Wfs*23 | Frame Shift Del (DEL) | VAF 38/130 reads (29%) | called by pindel, varscan2
- ABHD16A | c.567C>T p.H189= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV65452178; called by muse, mutect2, varscan2
- ACTL8 | c.117G>A p.K39= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV64862086; called by muse, mutect2, varscan2
- ALPP | c.675C>T p.G225= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV67397110; called by muse, mutect2, varscan2
- ANKMY2 | c.783G>A p.V261= | Silent (SNP) | VAF 50/132 reads (38%) | catalogued as COSV61012173; called by muse, mutect2, varscan2
- ANKRD11 | c.141C>T p.G47= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs200889723, COSV56360740; called by muse, mutect2, varscan2
- ANKRD34A | c.1179G>A p.P393= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV60161405; called by muse, mutect2, varscan2
- APPL1 | c.1299T>C p.S433= | Silent (SNP) | VAF 105/308 reads (34%) | catalogued as COSV55702214; called by muse, mutect2, varscan2
- ARMCX2 | c.177C>T p.A59= | Silent (SNP) | VAF 70/190 reads (37%) | catalogued as rs781894857, COSV57530747; called by muse, mutect2, varscan2
- ATXN2 | c.1788G>A p.P596= (on ENST00000550104; = p.P436= on NM_002973.4) | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs1326410629, COSV66484814; called by muse, mutect2, varscan2
- BAIAP3 | c.1716C>T p.N572= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs1239902011, COSV50104536; called by muse, mutect2
- BEST1 | c.813C>T p.L271= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as rs370397270; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C22orf23 | c.321C>T p.S107= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV50778241; called by muse, mutect2, varscan2
- CCDC141 | c.2385C>A p.V795= | Silent (SNP) | VAF 73/332 reads (22%) | catalogued as COSV55377896; called by muse, mutect2, varscan2
- CCDC167 | c.111C>T p.H37= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs1277889166, COSV64982676; called by muse, mutect2, varscan2
- CCN3 | c.657C>T p.S219= | Silent (SNP) | VAF 66/188 reads (35%) | catalogued as COSV52384578; called by muse, mutect2, varscan2
- CELA2B | c.16C>T p.L6= | Silent (SNP) | VAF 5/118 reads (4%) | catalogued as COSV62747825; called by muse, mutect2
- COL7A1 | c.8427C>T p.I2809= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs779725201, COSV56476873; called by muse, mutect2, varscan2
- COQ4 | c.780C>T p.H260= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs200203275; ClinVar: likely benign; called by muse, mutect2, varscan2
- CRB1 | c.234C>A p.P78= | Silent (SNP) | VAF 50/138 reads (36%) | catalogued as COSV66344720; called by muse, mutect2, varscan2
- CTDP1 | c.756C>T p.Y252= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs751409711, COSV50006140; called by muse, mutect2, varscan2
- DCT | c.405T>C p.P135= | Silent (SNP) | VAF 23/336 reads (7%) | catalogued as COSV65470104; called by muse, mutect2
- DENND5A | c.3195G>A p.L1065= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as COSV60236077; called by muse, mutect2, varscan2
- DLG5 | c.1704C>A p.T568= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV64948864; called by muse, mutect2, varscan2
- DNAAF1 | c.1770G>A p.T590= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs747916153, COSV58985252; called by muse, mutect2, varscan2
- DNAH1 | c.4017C>A p.I1339= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV70232329; called by muse, mutect2, varscan2
- DNMT1 | c.2364C>T p.N788= | Silent (SNP) | VAF 192/265 reads (72%) | catalogued as rs755858168, COSV61581458; called by muse, mutect2, varscan2
- DTX2 | c.513C>T p.S171= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs780368395, COSV56863090; called by muse, mutect2, varscan2
- EIF4A2 | c.429T>C p.N143= | Silent (SNP) | VAF 64/178 reads (36%) | catalogued as COSV56217939; called by muse, mutect2, varscan2
- EIF4G3 | c.2958T>C p.S986= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV51687991; called by muse, mutect2
- ELF2 | c.747T>C p.L249= (on ENST00000379550 / NM_001331036.2; = p.L189= on NM_006874.4) | Silent (SNP) | VAF 84/209 reads (40%) | catalogued as COSV55494461; called by muse, mutect2, varscan2
- EPB41 | c.1893C>T p.D631= (on ENST00000343067 / NM_001166005.2; = p.D422= on NM_203342.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV58050902; called by muse, mutect2, varscan2
- ESPL1 | c.1017C>T p.S339= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV57761039; called by muse, mutect2, varscan2
- ESPL1 | c.3109C>T p.L1037= | Silent (SNP) | VAF 34/138 reads (25%) | catalogued as COSV57761045; called by muse, mutect2, varscan2
- FAM168A | c.297G>A p.A99= (on ENST00000064778 / NM_001286050.2; = p.A90= on NM_015159.3) | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as rs756403446, COSV50358241; called by muse, mutect2, varscan2
- FASTKD3 | c.348A>G p.L116= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV52945398; called by muse, mutect2, varscan2
- FBN3 | c.5790C>A p.T1930= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV54460791; called by muse, mutect2, varscan2
- FLNC | c.3327C>T p.C1109= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV57960164; called by muse, mutect2
- GAREM1 | c.1665G>A p.K555= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV52512803; called by muse, mutect2, varscan2
- GMIP | c.2040C>T p.D680= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV52558268; called by muse, mutect2, varscan2
- GRK6 | c.168G>A p.L56= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV62683468; called by muse, mutect2, varscan2
- H2AC4 | c.346C>T p.L116= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV52519296; called by muse, mutect2, varscan2
- HIVEP3 | c.1728C>T p.S576= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV56019158; called by muse, varscan2
- HIVEP3 | c.1704C>T p.T568= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs778310281, COSV56019164; called by muse, varscan2
- ING1 | c.1107C>T p.C369= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs753383406, COSV58167518; called by muse, mutect2, varscan2
- JCAD | c.609T>C p.D203= | Silent (SNP) | VAF 22/324 reads (7%) | catalogued as rs1396374010, COSV64760732; called by muse, mutect2
- KCNC4 | c.1599C>T p.I533= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs770979171, COSV100873708, COSV63925104; called by muse, mutect2
- KIRREL1 | c.1896C>T p.R632= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV63289403; called by muse, mutect2, varscan2
- LOXL2 | c.2154C>T p.F718= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV56120439; called by muse, mutect2, varscan2
- LRRC71 | c.1095G>A p.T365= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs190061539, COSV61656506; called by muse, mutect2, varscan2
- LRRK1 | c.2340A>G p.A780= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV52619807; called by muse, mutect2, varscan2
- LZTR1 | c.2451G>A p.L817= | Silent (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2
- MARK1 | c.663C>A p.P221= | Silent (SNP) | VAF 63/172 reads (37%) | catalogued as COSV65067601, COSV65069498; called by muse, mutect2, varscan2
- MBP | c.783C>T p.Y261= (on ENST00000355994 / NM_001025101.2; = p.Y143= on NM_002385.3) | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs147953101; called by muse, mutect2, varscan2
- MDC1 | c.1203C>T p.N401= | Silent (SNP) | VAF 14/230 reads (6%) | catalogued as COSV64525785; called by muse, mutect2
- MED26 | c.618C>A p.G206= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV54661729; called by muse, varscan2
- MEST | c.897G>A p.T299= | Silent (SNP) | VAF 66/194 reads (34%) | catalogued as rs782432630, COSV56229197; called by muse, mutect2, varscan2
- MGAT3 | c.1434C>T p.S478= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV57866855; called by muse, mutect2, varscan2
- MORN1 | c.228C>T p.R76= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs777478228, COSV58100802; called by muse, mutect2, varscan2
- MTMR6 | c.1119C>A p.I373= | Silent (SNP) | VAF 6/148 reads (4%) | catalogued as COSV67809047; called by muse, mutect2
- NEB | c.19603C>A p.R6535= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV51437348, COSV51465619; called by muse, mutect2, varscan2
- NOTCH3 | c.1662C>T p.C554= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs772251287, COSV54641626; called by muse, mutect2, varscan2
- NSD3 | c.1194G>A p.Q398= | Silent (SNP) | VAF 63/187 reads (34%) | catalogued as COSV57620727; called by muse, mutect2, varscan2
- OR10H1 | c.369C>T p.Y123= | Silent (SNP) | VAF 49/126 reads (39%) | catalogued as rs779333750, COSV58472402; called by muse, mutect2, varscan2
- OR5D18 | c.660G>A p.A220= | Silent (SNP) | VAF 93/292 reads (32%) | catalogued as rs779827741, COSV61737938, COSV61738052; called by muse, mutect2, varscan2
- OTUB1 | c.684C>T p.S228= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as rs200423792, COSV55362192; called by muse, mutect2, varscan2
- PAGE2 | c.186T>A p.A62= | Silent (SNP) | VAF 52/169 reads (31%) | catalogued as COSV66596113; called by muse, mutect2, varscan2
- PARP14 | c.1134G>A p.P378= | Silent (SNP) | VAF 115/422 reads (27%) | catalogued as rs770611577, COSV71735183, COSV71735629; called by muse, mutect2, varscan2
- PAX8 | c.78G>A p.L26= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs766493114, COSV54510767; called by muse, mutect2, varscan2
- PCDHB11 | c.2079G>A p.A693= | Silent (SNP) | VAF 50/110 reads (45%) | catalogued as rs373740953, COSV61310974; called by muse, mutect2, varscan2
- PCDHB5 | c.1806G>A p.S602= | Silent (SNP) | VAF 48/144 reads (33%) | catalogued as COSV50659090; called by muse, mutect2, varscan2
- PFKFB4 | c.1047C>A p.A349= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV51681930; called by muse, mutect2, varscan2
- PHKG2 | c.1131G>A p.R377= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as COSV100079882, COSV60312897; called by muse, mutect2, varscan2
- PIGF | c.225C>T p.H75= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as COSV53231920; called by muse, mutect2, varscan2
- PLA2G4F | c.315T>C p.A105= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV51828296; called by muse, mutect2, varscan2
- PNMA5 | c.360G>A p.V120= | Silent (SNP) | VAF 51/168 reads (30%) | catalogued as COSV62625915; called by muse, mutect2, varscan2
- PNMA5 | c.42C>T p.D14= | Silent (SNP) | VAF 57/161 reads (35%) | catalogued as COSV62625924; called by muse, mutect2, varscan2
- PPFIA4 | c.1671G>A p.T557= (on ENST00000447715; = p.V547M on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs753419187, COSV55318582; called by muse, mutect2
- PRRC2A | c.2130G>A p.R710= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV65687977; called by muse, mutect2, varscan2
- PRSS1 | c.360C>T p.N120= | Silent (SNP) | VAF 72/186 reads (39%) | catalogued as rs606231348; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- QRICH2 | c.4560C>T p.S1520= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs756493374, COSV53155436, COSV53156511; called by muse, mutect2, varscan2
- RAB25 | c.117C>T p.H39= | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as rs1173847672, COSV63107798; called by muse, mutect2
- RBFA | c.636A>G p.V212= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV51534559; called by muse, mutect2, varscan2
- RFX1 | c.618A>G p.P206= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV54331838; called by muse, mutect2, varscan2
- RPS6KA2 | c.1281A>G p.S427= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs1257948892, COSV55825042; called by mutect2, varscan2
- RPUSD4 | c.60C>T p.C20= | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as COSV53599792; called by muse, mutect2, varscan2
- SAMD8 | c.687G>A p.L229= | Silent (SNP) | VAF 96/302 reads (32%) | catalogued as COSV65510448; called by muse, mutect2, varscan2
- SASH1 | c.3204A>G p.T1068= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV66563604; called by muse, mutect2, varscan2
- SASH3 | c.861G>A p.L287= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV63556246; called by muse, mutect2, varscan2
- SERPINB7 | c.1035A>T p.V345= | Silent (SNP) | VAF 55/147 reads (37%) | catalogued as COSV60534926; called by muse, mutect2, varscan2
- SLC38A8 | c.1048C>T p.L350= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs1017305851, COSV55308253; called by muse, mutect2, varscan2
- SLC44A2 | c.975T>C p.L325= | Silent (SNP) | VAF 135/199 reads (68%) | catalogued as COSV59837926; called by muse, mutect2, varscan2
- SPEN | c.1692T>C p.Y564= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV65365003; called by muse, mutect2, varscan2
- SPINK5 | c.1797C>A p.T599= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV56258651; called by muse, mutect2, varscan2
- SPPL2B | c.339C>T p.R113= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs192000517, COSV66316756, COSV66316920, COSV66317183; called by muse, mutect2, varscan2
- SPTBN1 | c.3657C>T p.D1219= | Silent (SNP) | VAF 44/97 reads (45%) | catalogued as rs567753600, COSV61690905; called by muse, mutect2, varscan2
- SRRM2 | c.5971C>A p.R1991= | Silent (SNP) | VAF 85/224 reads (38%) | catalogued as rs1308768786, COSV51941284; called by muse, mutect2, varscan2
- STAG2 | c.3609C>T p.N1203= | Silent (SNP) | VAF 72/244 reads (30%) | catalogued as COSV54365922; called by muse, mutect2, varscan2
- SVOPL | c.1284C>T p.R428= (on ENST00000419765; = p.R276= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs1042230726, COSV55993375; called by muse, mutect2, varscan2
- SYNJ2 | c.1968G>A p.T656= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs758367538, COSV62899038; called by muse, mutect2
- SYP | c.786C>T p.Y262= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs888529856, COSV54296163; called by muse, mutect2, varscan2
- TAF2 | c.1458G>A p.Q486= | Silent (SNP) | VAF 73/232 reads (31%) | catalogued as COSV65419501; called by muse, mutect2, varscan2
- TAT | c.822C>A p.S274= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as COSV63533217; called by muse, mutect2
- TBKBP1 | c.846G>A p.A282= | Silent (SNP) | VAF 64/176 reads (36%) | catalogued as rs369998319; called by muse, mutect2, varscan2
- TENM1 | c.1696C>T p.L566= | Silent (SNP) | VAF 182/454 reads (40%) | catalogued as COSV64437705; called by muse, mutect2, varscan2
- TFB2M | c.151C>T p.L51= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as COSV63620806; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1170G>C p.L390= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV51514287; called by muse, mutect2, varscan2
- TLR7 | c.282C>A p.I94= | Silent (SNP) | VAF 263/757 reads (35%) | catalogued as COSV66123804, COSV66125131; called by muse, mutect2, varscan2
- TNRC6B | c.4389A>G p.P1463= (on ENST00000454349 / NM_001162501.2; = p.P1353= on NM_015088.3) | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV57301773; called by muse, mutect2, varscan2
- TRH | c.393G>A p.Q131= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV57015398; called by muse, mutect2
- TRIM16L | c.549G>A p.T183= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as COSV67459661; called by muse, mutect2, varscan2
- UBA5 | c.964C>T p.L322= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as rs766063059, COSV53904685; called by muse, mutect2, varscan2
- UGT1A1 | c.573C>A p.S191= | Silent (SNP) | VAF 13/294 reads (4%) | catalogued as COSV59393688; called by muse, mutect2
- UMOD | c.1356G>A p.G452= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV56777666; called by muse, mutect2, varscan2
- USP13 | c.384C>T p.S128= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as rs759765443, COSV55864235; called by muse, mutect2, varscan2
- VPS18 | c.1962C>T p.N654= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV55028751; called by muse, mutect2, varscan2
- YWHAQ | c.232C>T p.L78= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs1289917939, COSV53004105; called by muse, mutect2, varscan2
- ZNF282 | c.1794C>A p.G598= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV50481628; called by muse, mutect2, varscan2
- ZNF462 | c.3510C>T p.P1170= | Silent (SNP) | VAF 188/428 reads (44%) | catalogued as rs1363217375, COSV52931294; called by muse, mutect2, varscan2
- ZSCAN1 | c.663C>T p.L221= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs199732051, COSV56606527; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824220 A>G | 5'Flank (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- ARIH2 | chr3:48918760 C>A | 5'Flank (SNP) | VAF 9/18 reads (50%) | catalogued as COSV62705523; called by muse, mutect2, varscan2
- B4GALNT1 | chr12:57622598 G>A | 3'Flank (SNP) | VAF 18/398 reads (5%) | catalogued as COSV57543806; called by muse, mutect2
- BNIP1 | c.178-2760_178-2714delinsAGCCAGTTCTCTATCAAAGGGCATTTATTTGGACTGCTTCCACA | Intron (DEL) | VAF 12/135 reads (9%) | called by pindel, varscan2*
- DCHS2 | n.7294del | RNA (DEL) | VAF 73/252 reads (29%) | catalogued as COSV100600914; called by mutect2, pindel, varscan2
- FMN1 | c.2044-1845G>A | Intron (SNP) | VAF 29/132 reads (22%) | catalogued as COSV57928141; called by muse, mutect2, varscan2
- FSD1 | c.*6del | 3'UTR (DEL) | VAF 5/23 reads (22%) | catalogued as rs1475518993; called by mutect2, varscan2
- GUCA1A | c.-2C>T | 5'UTR (SNP) | VAF 25/69 reads (36%) | catalogued as COSV99273973; called by muse, mutect2, varscan2
- HLA-F | chr6:29727026 del T | 3'Flank (DEL) | VAF 138/530 reads (26%) | catalogued as COSV52576394; called by mutect2, varscan2
- MAPKAPK2 | c.1059+150C>T | Intron (SNP) | VAF 29/83 reads (35%) | catalogued as COSV54317563; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640466 C>T | 3'Flank (SNP) | VAF 24/89 reads (27%) | catalogued as rs147595258; called by muse, mutect2, varscan2
- NBPF25P | n.961C>T | RNA (SNP) | VAF 200/785 reads (25%) | catalogued as rs1313259036; called by muse, mutect2, varscan2
- NXPH4 | c.*2G>A | 3'UTR (SNP) | VAF 6/14 reads (43%) | catalogued as rs773721465, COSV100197168; called by muse, mutect2, varscan2
- SNORD116-22 | n.78G>A | RNA (SNP) | VAF 120/380 reads (32%) | catalogued as rs201807241; called by muse, mutect2, varscan2
- SPATA13 | c.290-5336del | Intron (DEL) | VAF 60/158 reads (38%) | catalogued as rs749470297; called by mutect2, varscan2
- STAG3L4 | n.493A>G | RNA (SNP) | VAF 43/120 reads (36%) | catalogued as rs1207711117; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1587G>A | Intron (SNP) | VAF 132/403 reads (33%) | catalogued as COSV100678507; called by muse, mutect2, varscan2
